Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACK, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACK-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: HCC

Specimen : Liver

Gross Photo :

GROSS:

1. Specimen:

Liver: 10.0 x 9.5 x 5.5 cm, 169.5gm, unfixed
8.0 x 6.0 x 5.2 cm, 66.0 gm, unfixed

2. Tumor location: right

Tumor number: One

Tumor size: 5.3 x 4.9 x 5.5 cm

3. Satellite nodule: no

4. Gross type

HCC: expanding nodular

5. Tumor necrosis: no

6. Hemorrhage/peliosis: yes (5-10 %)

7. Portal vein invasion: no

8. Bile duct invasion: no

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0

MD 5/19/14

Gross photo present.

Blocks

TB, T1-5, tumor mass x 6

NB, A, non-tumorous tissue x 2

RM, resection margin x 1

MICROSCOPIC:

1. Hepatocellular carcinoma:

1-1. Differentiation

The worst differentiation II

The major differentiation II

1-2. Histologic type: trabecular

1-3. Cell type: clear

1-4. Fatty change: no

2. Fibrous capsule formation: complete capsule

3. Capsular infiltration: no

4. Septum formation: yes

5. Surgical resection margin invasion: no, margin of the clearance (3.0 mm)

6. Serosal invasion: no

7. Portal vein invasion: no

[page 2 of 2]
8. Bile duct invasion: no
9. Hepatic vein invasion: no
10. Hepatic artery invasion: no
11. Microvessel invasion: yes
12. Intrahepatic metastasis: no
13. Multicentric occurrence: no

NOT reported. Gross:

Urine, smear, negative

Urine, smear, negative

Urine, smear, negative

Liver, ectomy, hepatocellular carcinoma, cirrhosis
T56000, P10, M81703, M49500

DIAGNOSIS:

Liver, right lobe, lobectomy:
Hepatocellular carcinoma, well differentiated
Cirrhosis

Suggestion :

Source: NCI Genomic Data Commons file 9978097d-a0b2-41de-bbbe-4306f549161d (TCGA-DD-AACK.B41B7C44-ED04-46EB-AD41-271456ECA762.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).